Somatic mutation profile of tumor specimen TARGET-10-PANTSM-03A (aliquot TARGET-10-PANTSM-03A-01D) from TARGET case TARGET-10-PANTSM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,591 days).
Specimen TARGET-10-PANTSM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ab469c5-c82c-40e7-88ce-afffa8c412af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTSM-14A (Bone Marrow Normal), aliquot TARGET-10-PANTSM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76959ed5-f010-42ce-94e3-05262344dde2

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRMS1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV60820597; called by muse, mutect2
- CORIN | c.1619G>T p.C540F | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770141559, COSV56697563; called by muse, mutect2, varscan2
- HIC2 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV68042054; called by mutect2, varscan2
- SOS1 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 14/405 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67676433; called by muse, mutect2
- TM7SF2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as rs551357064, COSV54207136; called by muse, mutect2, varscan2
- HIC2 | c.1632dup p.R545Afs*21 | Frame Shift Ins (INS) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- PRPF4B | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- CPS1 | c.4197C>T p.N1399= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs548201746, COSV51801812; called by muse, mutect2
- PEG3 | c.789C>T p.D263= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs142177720, COSV55627105; called by muse, mutect2, varscan2
- EIF4A2 | c.771+61C>A | Intron (SNP) | VAF 135/295 reads (46%) | catalogued as COSV56218293; called by muse, mutect2, varscan2
